Somatic mutation profile of tumor specimen MMRF_1832_1_BM_CD138pos (aliquot MMRF_1832_1_BM_CD138pos_T1_KBS5U_L05385) from MMRF case MMRF_1832, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.8 years (26,215 days).
Specimen MMRF_1832_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1028a2e0-1ad1-45ed-88da-abc8e7917a02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1832_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1832_1_PB_Whole_C3_KBS5U_L05394; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ca1e546-f77e-4bf6-9f95-f4f44b129807

The open-access MAF lists 66 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, 3'UTR 13, Intron 9, Silent 6, 5'UTR 5, Frame Shift Del 1, 5'Flank 1, 3'Flank 1, RNA 1, Nonsense Mutation 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL22A1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs777346782, COSV57323338; called by muse, mutect2, varscan2
- EIF4A1 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 29/102 reads (28%) | catalogued as COSV51510033, COSV51511514; called by muse, mutect2, varscan2
- EIF4G3 | c.1987A>G p.M663V | Missense Mutation (SNP) | VAF 74/132 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs140416357; called by muse, mutect2, varscan2
- IGLV3-25 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.047); catalogued as rs758394229; called by muse, mutect2, varscan2
- IGLV4-3 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.481); catalogued as rs576246152; called by muse, mutect2, varscan2
- IRF6 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.158); catalogued as COSV100884030; called by muse, mutect2, varscan2
- LRRC66 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1198241954, COSV58633557, COSV58634236; called by muse, mutect2
- MUC16 | c.29615C>A p.T9872K | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.943); catalogued as rs762980584; called by muse, mutect2, varscan2
- PCDH7 | c.2543C>T p.A848V | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs376534155; called by muse, mutect2, varscan2
- PRPF19 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs761083429, COSV57129363; called by muse, mutect2, varscan2
- RRP9 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.222); catalogued as COSV51754759; called by muse, mutect2, varscan2
- SPECC1L | c.2905A>C p.M969L | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV58658794; called by muse, mutect2, varscan2
- SRP72 | c.1370A>G p.K457R | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.92); catalogued as rs1226265544; called by muse, mutect2, varscan2
- BCAN | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 114/223 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- EGR1 | c.191G>C p.S64T | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, varscan2
- FAT2 | c.9329C>T p.A3110V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FLT4 | c.3448A>G p.N1150D | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV2-70D | c.340T>G p.Y114D | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- KDM5C | c.229-2A>T p.X77_splice | Splice Site (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- KMT2D | c.3287C>T p.S1096F | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- LAMA2 | c.1568T>C p.V523A | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2
- MUC16 | c.20119T>A p.S6707T | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- NRK | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHA7 | c.478A>G p.N160D | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SENP3 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SHROOM3 | c.1871_1893del p.E624Gfs*39 | Frame Shift Del (DEL) | VAF 33/177 reads (19%) | called by mutect2, pindel, varscan2
- SPOP | c.185dup p.N62Kfs*2 | Frame Shift Ins (INS) | VAF 22/80 reads (28%) | called by mutect2, pindel, varscan2
- TOMM6 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- WDR97 | c.626G>A p.R209K | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF274 | c.398C>A p.A133D (on ENST00000610905; = p.A28D on NM_016324.3) | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ATP1B4 | c.348C>T p.Y116= (on ENST00000218008 / NM_001142447.3; = p.Y112= on NM_012069.5) | Silent (SNP) | VAF 28/28 reads (100%) | called by muse, mutect2, varscan2
- CCSER1 | c.114A>T p.T38= | Silent (SNP) | VAF 47/86 reads (55%) | called by muse, mutect2, varscan2
- DNAH1 | c.8574C>T p.P2858= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as rs1435085952; called by muse, mutect2, varscan2
- MYH7 | c.3567C>T p.A1189= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs1165812799; ClinVar: likely benign; called by muse, mutect2
- PPP2R1A | c.1524G>A p.L508= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as rs80165164; called by muse, mutect2, varscan2
- RGS22 | c.382A>C p.R128= | Silent (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- AC016705.2 | n.200A>C | RNA (SNP) | VAF 131/281 reads (47%) | catalogued as rs1240109186; called by muse, mutect2, varscan2
- ADGRE3 | c.1921-2231G>A | Intron (SNP) | VAF 34/78 reads (44%) | catalogued as rs925776558; called by muse, mutect2, varscan2
- ANO7 | c.471+270C>A | Intron (SNP) | VAF 23/125 reads (18%) | called by muse, mutect2, varscan2
- CANX | c.*1625_*1626del | 3'UTR (DEL) | VAF 29/96 reads (30%) | called by mutect2, pindel, varscan2
- CHRAC1 | c.*918A>T | 3'UTR (SNP) | VAF 5/38 reads (13%) | called by muse, varscan2
- CORIN | c.2068+266G>C | Intron (SNP) | VAF 48/96 reads (50%) | called by muse, mutect2, varscan2
- FP565260.6 | c.*2273A>G | 3'UTR (SNP) | VAF 4/46 reads (9%) | catalogued as rs1466789100; called by muse, mutect2
- GDAP1L1 | c.*996T>A | 3'UTR (SNP) | VAF 51/105 reads (49%) | called by muse, mutect2, varscan2
- IDE | c.1154-43A>T | Intron (SNP) | VAF 49/135 reads (36%) | called by muse, mutect2, varscan2
- ITGB6 | c.*884G>A | 3'UTR (SNP) | VAF 30/62 reads (48%) | catalogued as rs1056731813; called by muse, mutect2, varscan2
- LIPC | c.88+4642A>G | Intron (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- OGFRL1 | c.-99C>T | 5'UTR (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- PCARE | c.*1966C>T | 3'UTR (SNP) | VAF 18/104 reads (17%) | catalogued as rs1042138792; called by muse, mutect2, varscan2
- PIGM | c.*1077A>G | 3'UTR (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- PSMG4 | c.*281A>G | 3'UTR (SNP) | VAF 5/30 reads (17%) | catalogued as rs1005003370; called by mutect2, varscan2
- ROBO2 | c.-210C>G | 5'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- RPP21 | c.310+77G>C | Intron (SNP) | VAF 18/33 reads (55%) | called by muse, mutect2, varscan2
- SLC35F3 | c.*956C>T | 3'UTR (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- SLC3A2 | chr11:62853292 C>A | 5'Flank (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- SND1 | c.2305-58G>A | Intron (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- SPATC1 | c.-25C>T | 5'UTR (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- SPN | c.*3022T>C | 3'UTR (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2, varscan2
- TM9SF1 | chr14:24188908 T>C | 3'Flank (SNP) | VAF 72/149 reads (48%) | called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.*481T>A | 3'UTR (SNP) | VAF 19/34 reads (56%) | catalogued as rs924546976; called by muse, mutect2, varscan2
- TMEM44 | c.754-57C>T | Intron (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- TTN | c.10360+1425T>G | Intron (SNP) | VAF 69/147 reads (47%) | called by muse, mutect2, varscan2
- VEGFC | c.-153C>T | 5'UTR (SNP) | VAF 29/49 reads (59%) | called by muse, mutect2, varscan2
- ZBED4 | c.*1110_*1113del | 3'UTR (DEL) | VAF 10/63 reads (16%) | catalogued as rs1172960419; called by pindel, varscan2
- ZBTB49 | c.*227C>T | 3'UTR (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- ZC3H15 | c.-46G>A | 5'UTR (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
